Somatic mutation profile of tumor specimen TCGA-ZU-A8S4-01A (aliquot TCGA-ZU-A8S4-01A-11D-A417-09) from TCGA case TCGA-ZU-A8S4, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 52.7 years (19,264 days).
Specimen TCGA-ZU-A8S4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16764f1a-47e0-430b-bb77-1570fb1b7bfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZU-A8S4-10A (Blood Derived Normal), aliquot TCGA-ZU-A8S4-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33e44387-7dc6-42c0-a551-184eeaae4e28

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDH12 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99063507; called by muse, mutect2
- GRIK2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1161694919, COSV59732229, COSV59756626; called by muse, mutect2
- IRS1 | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1051275735; called by muse, mutect2
- KMT2C | c.2573G>T p.W858L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs111493987, COSV51367709; called by muse, mutect2
- NTF3 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58417756; called by muse, mutect2, varscan2
- PTPN4 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99751089; called by mutect2, varscan2
- RHOBTB1 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100558361; called by muse, mutect2, varscan2
- RTTN | c.4436C>T p.A1479V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs919837600; called by muse, mutect2, varscan2
- SCN8A | c.5149C>T p.R1717C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1451912147; called by muse, mutect2, varscan2
- SLC9A3 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1241269104; called by muse, mutect2
- SPPL2C | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs767879204, COSV61292841; called by muse, mutect2, varscan2
- TRPC4 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV58999388; called by muse, mutect2, varscan2
- USP9X | c.7096C>T p.R2366* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV61069631; called by muse, mutect2, varscan2
- ZNF423 | c.68C>T p.S23L (on ENST00000563137 / NM_001379286.1; = p.S15L on NM_015069.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.04); catalogued as rs377503772; called by muse, mutect2, varscan2
- ALMS1 | c.7549A>C p.M2517L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP28 | c.997G>C p.G333R (on ENST00000383472 / NM_001366230.1; = p.G174R on NM_001010000.3) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ARID1A | c.5459_5463del p.N1820Tfs*9 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- BBS7 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- CAND1 | c.2716C>T p.Q906* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- DDB2 | c.78T>G p.S26R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- DZIP3 | c.1100C>G p.T367S | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2
- GPR85 | c.788C>G p.A263G | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- GRB14 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IFNGR1 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PCDHGA4 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- RABGAP1 | c.841G>C p.A281P | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- RABGAP1 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- RNF220 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SLC22A10 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC8A3 | c.817A>C p.I273L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2
- UGGT1 | c.209A>C p.E70A | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- KIAA2026 | c.387C>T p.F129= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1312646559; called by mutect2, varscan2
- NPTN | c.360C>T p.N120= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1277120114, COSV54738030; called by muse, mutect2, varscan2
- OR2L2 | c.519C>T p.I173= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- PI15 | c.237C>A p.G79= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV52644024; called by muse, mutect2, varscan2
- TOGARAM2 | c.2838C>T p.S946= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs764828299; called by muse, mutect2, varscan2
- TUBB | c.648G>A p.K216= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- C15orf48 | c.*35A>G | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
